Somatic mutation profile of tumor specimen C3L-04244-54 (aliquot CPT0259780002) from CPTAC case C3L-04244, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 77.5 years (28,299 days).
Specimen C3L-04244-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ba9b1e4-07ce-4c32-8066-225ad75da900.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04244-50 (Buccal Cell Normal), aliquot CPT0259770003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/018b3695-1262-4f1d-8a84-9162dd9c65db

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 3, Frame Shift Del 1, Nonsense Mutation 1, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 102/263 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.1512C>A p.D504E | Missense Mutation (SNP) | VAF 107/223 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs1394876071; called by muse, mutect2, varscan2
- COL27A1 | c.5450G>A p.R1817H | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs200142542; called by muse, mutect2, varscan2
- H3C10 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 121/284 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.113); catalogued as rs1290595614, COSV104411750; called by muse, mutect2, varscan2
- RAD21 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 6/147 reads (4%) | catalogued as COSV52056480; called by muse, mutect2
- THAP12 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs779072571, COSV52610830; called by muse, mutect2, varscan2
- AGER | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 107/218 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GALR1 | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK4 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MKRN3 | c.1318G>C p.A440P | Missense Mutation (SNP) | VAF 124/248 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SH3PXD2A | c.854T>C p.I285T (on ENST00000369774 / NM_001365079.1; = p.I257T on NM_014631.2) | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- STAG2 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TET2 | c.2673del p.Q891Hfs*30 | Frame Shift Del (DEL) | VAF 220/491 reads (45%) | called by mutect2, varscan2
- TRIM33 | c.900G>C p.Q300H | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- TRPM6 | c.4171A>T p.T1391S | Missense Mutation (SNP) | VAF 176/343 reads (51%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TYSND1 | c.405G>A p.L135= | Silent (SNP) | VAF 53/104 reads (51%) | catalogued as rs1474685269; called by muse, mutect2, varscan2
- ATL3 | chr11:63671615 G>A | 5'Flank (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- DLC1 | c.1348+28885C>A | Intron (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- IKBKE | c.1836-152G>A | Intron (SNP) | VAF 44/117 reads (38%) | catalogued as rs782382820, COSV65624007; called by muse, mutect2, varscan2
- PPP2R5A | c.928-3679C>T | Intron (SNP) | VAF 59/137 reads (43%) | called by muse, mutect2, varscan2
